Somatic mutation profile of tumor specimen CDDP-ACRK-TTP1-A (aliquot CDDP-ACRK-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACRK, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 70 years.
Specimen CDDP-ACRK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 863134ea-6dc5-4201-be4b-d3f856876b48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACRK-NB1-A (Blood Derived Normal), aliquot CDDP-ACRK-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e29558bb-e99b-4300-98fd-fff82d86fe20

The open-access MAF lists 88 somatic variants for this specimen: 62 protein-altering or splice-affecting, 15 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Intron 6, Nonsense Mutation 4, Splice Region 3, Splice Site 3, 5'Flank 3, Frame Shift Del 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.994-2A>G p.X332_splice | Splice Site (SNP) | VAF 225/260 reads (87%) | hotspot (GDC flag); catalogued as rs867389695, CS159286, COSV52692098, COSV52692518, COSV53122371; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 122/161 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752752402, COSV51472654; called by muse, mutect2, varscan2
- ADGRL2 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755815823, COSV54666541; called by muse, mutect2, varscan2
- B4GALNT1 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.506); catalogued as rs767768866, COSV57543059; called by muse, mutect2, varscan2
- CACNA1G | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs965460888; called by muse, mutect2, varscan2
- ELOA | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as rs377449904; called by muse, mutect2, varscan2
- FREM3 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs1031639941; called by muse, mutect2
- GJB4 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs539139170, COSV58356277, COSV58356883; called by muse, mutect2, varscan2
- GPAT4 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.474); catalogued as rs1419230409; called by muse, mutect2, varscan2
- GRM8 | c.301del p.R101Afs*17 | Frame Shift Del (DEL) | VAF 58/171 reads (34%) | catalogued as COSV58822148; called by mutect2, pindel, varscan2
- GTF2I | c.1327C>T p.R443C (on ENST00000573035 / NM_032999.4; = p.R402C on NM_001518.5) | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs587719538; called by muse, varscan2
- IQGAP1 | c.3598A>G p.I1200V | Missense Mutation (SNP) | VAF 97/129 reads (75%) | SIFT tolerated (0.38); PolyPhen benign (0.098); catalogued as rs1346162404; called by muse, mutect2, varscan2
- ITGB4 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 155/356 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV52324269; called by muse, mutect2, varscan2
- MYO10 | c.5938G>A p.V1980I | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.153); catalogued as rs372353260; called by muse, mutect2, varscan2
- MYO3B | c.1291T>C p.C431R | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58694284; called by muse, mutect2, varscan2
- NMD3 | c.1301A>G p.D434G | Missense Mutation (SNP) | VAF 56/73 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs758964547; called by muse, mutect2, varscan2
- OR2M7 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV58737687; called by muse, mutect2, varscan2
- OR8B4 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.576); catalogued as rs948156651; called by muse, mutect2, varscan2
- PFKFB3 | c.1499C>T p.T500M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | PolyPhen benign (0.001); catalogued as rs150176706, COSV100431683; called by muse, mutect2, varscan2
- PRKX | c.876C>T p.N292= | Splice Region (SNP) | VAF 44/185 reads (24%) | catalogued as rs1301840503, COSV53322064; called by muse, mutect2, varscan2
- RGL1 | c.2233C>T p.R745W (on ENST00000360851 / NM_001297672.2; = p.R780W on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.649); catalogued as rs561043926; called by muse, mutect2, varscan2
- RTTN | c.2731C>G p.P911A | Missense Mutation (SNP) | VAF 60/94 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs764020186; called by muse, mutect2, varscan2
- SGMS2 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs760890348; called by muse, mutect2, varscan2
- SYT6 | c.*54G>T | Splice Region (SNP) | VAF 32/121 reads (26%) | catalogued as rs1161311591; called by muse, mutect2, varscan2
- TIAM1 | c.4027C>T p.R1343* | Nonsense Mutation (SNP) | VAF 94/121 reads (78%) | catalogued as COSV54545064; called by muse, mutect2, varscan2
- YEATS2 | c.3110T>C p.I1037T | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as rs1194442614; called by muse, mutect2, varscan2
- ADGRG6 | c.849A>C p.K283N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ALS2 | c.4887C>A p.D1629E | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.968); called by muse, mutect2
- AP5M1 | c.1258G>C p.D420H | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- APBB2 | c.1399G>A p.G467R (on ENST00000295974 / NM_001166050.2; = p.G468R on NM_004307.2) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLNK | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 76/102 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CMYA5 | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH5 | c.7753-2_7767del p.X2585_splice | Splice Site (DEL) | VAF 14/104 reads (13%) | called by mutect2, pindel
- FOXD4L4 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 79/868 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.384); called by muse, mutect2
- GANC | c.2653G>A p.V885M | Missense Mutation (SNP) | VAF 76/107 reads (71%) | PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GEN1 | c.2506G>A p.G836S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GPATCH8 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 72/200 reads (36%) | called by muse, mutect2, varscan2
- GRAMD4 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ITSN2 | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2
- KCNN3 | c.1018C>G p.R340G | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP2K7 | c.1103G>C p.R368T | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MMP15 | c.230A>G p.Q77R | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- MTNR1A | c.188A>C p.N63T | Missense Mutation (SNP) | VAF 156/383 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MTPAP | c.158-2A>T p.X53_splice | Splice Site (SNP) | VAF 158/460 reads (34%) | called by muse, varscan2
- MUC20 | c.363_372delinsTCTGA p.A122Lfs*11 | Frame Shift Del (DEL) | VAF 24/236 reads (10%) | called by pindel, varscan2*
- PCSK5 | c.4900A>G p.N1634D | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE4B | c.1382C>G p.T461R | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGAM4 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 66/279 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- RAX | c.84C>A p.S28R | Missense Mutation (SNP) | VAF 54/72 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- RIMS2 | c.1718A>C p.K573T (on ENST00000666250 / NM_001348490.2; = p.K381T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC63 | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 73/505 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLITRK2 | c.1892T>C p.L631S | Missense Mutation (SNP) | VAF 84/159 reads (53%) | SIFT tolerated (0.53); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SMAD4 | c.213T>A p.C71* | Nonsense Mutation (SNP) | VAF 76/98 reads (78%) | called by muse, mutect2, varscan2
- TBX5 | c.1406A>T p.Q469L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TOPORS | c.1069A>G p.S357G | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- TRPM3 | c.1278+3A>G | Splice Region (SNP) | VAF 94/346 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.81857T>A p.V27286D (on ENST00000591111; = p.V19862D on NM_003319.4) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | PolyPhen benign (0.259); called by muse, varscan2
- TTN | c.20329T>A p.F6777I (on ENST00000591111; = p.F5850I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/136 reads (38%) | PolyPhen benign (0.154); called by muse, mutect2, varscan2
- WDPCP | c.2133G>T p.L711F | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- ZC2HC1A | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF480 | c.1504C>G p.R502G | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by mutect2, varscan2
- ZNF572 | c.391C>G p.P131A | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2
- CCDC130 | c.498G>C p.L166= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as rs1467623155; called by muse, mutect2, varscan2
- DKK2 | c.312G>T p.R104= | Silent (SNP) | VAF 56/168 reads (33%) | called by muse, mutect2, varscan2
- ERVV-2 | c.1356C>G p.P452= | Silent (SNP) | VAF 57/138 reads (41%) | called by muse, mutect2, varscan2
- HFM1 | c.57A>C p.P19= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- HMCN1 | c.3177C>T p.Y1059= | Silent (SNP) | VAF 100/216 reads (46%) | catalogued as rs757058220, COSV54881874; called by muse, mutect2, varscan2
- KMT2C | c.5796A>G p.V1932= | Silent (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- NOTCH3 | c.5100C>T p.D1700= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as rs776639004, COSV54634674; called by muse, mutect2, varscan2
- OR5T2 | c.858A>C p.G286= | Silent (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- PCDHA1 | c.1884G>A p.T628= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV65373643; called by muse, mutect2, varscan2
- RWDD2B | c.36G>A p.P12= | Silent (SNP) | VAF 66/88 reads (75%) | catalogued as rs1327980023; called by muse, mutect2, varscan2
- SULT6B1 | c.777C>G p.R259= (on ENST00000535679 / NM_001367551.1; = p.R221= on NM_001032377.2) | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1414377413; called by muse, mutect2
- THBS2 | c.105C>T p.I35= | Silent (SNP) | VAF 41/48 reads (85%) | called by muse, mutect2, varscan2
- ZDHHC3 | c.174G>A p.A58= | Silent (SNP) | VAF 173/407 reads (43%) | catalogued as rs1361663028, COSV99943430; called by muse, mutect2, varscan2
- ZNF235 | c.378T>A p.I126= | Silent (SNP) | VAF 32/219 reads (15%) | called by muse, mutect2, varscan2
- ZNF417 | c.1200A>G p.R400= | Silent (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444265 G>A | 5'Flank (SNP) | VAF 54/126 reads (43%) | called by muse, mutect2, varscan2
- CDK10 | c.87+901A>G | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as rs1334746439; called by muse, varscan2
- CLEC16A | c.2642-9272C>A | Intron (SNP) | VAF 31/47 reads (66%) | called by muse, mutect2, varscan2
- DCAF11 | chr14:24110374 A>G | 5'Flank (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- DIABLO | c.-37+1416G>T | Intron (SNP) | VAF 186/458 reads (41%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102234C>A | Intron (SNP) | VAF 8/69 reads (12%) | catalogued as rs760825807; called by mutect2, varscan2
- INO80B | c.59-48C>T | Intron (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- MOB4P2 | chr11:86823395 G>C | 5'Flank (SNP) | VAF 62/147 reads (42%) | called by muse, mutect2, varscan2
- RPL34-DT | n.1088+512A>G | Intron (SNP) | VAF 5/27 reads (19%) | catalogued as rs1451899258; called by mutect2, varscan2
- SHROOM4 | c.*1378T>G | 3'UTR (SNP) | VAF 9/81 reads (11%) | catalogued as rs1557245541; called by mutect2, varscan2
- SQLE | c.-879G>A | 5'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
